Somatic mutation profile of tumor specimen RC-B65M-TBP1-A (aliquot RC-B65M-TBP1-A-1-0-D-A93N-47) from RC case RC-B65M, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 40.4 years (14,739 days).
Specimen RC-B65M-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d7f20c4-d77b-46e6-914f-2c3af89f6fe5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65M-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65M-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e2e28a7-bdc4-4911-9950-86394b08d564

The open-access MAF lists 88 somatic variants for this specimen: 60 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 20, Intron 5, Frame Shift Del 3, Nonsense Mutation 3, RNA 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT3 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 75/108 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747639500, COSV52882933, COSV52884030, COSV52885662; called by muse, mutect2, varscan2
- ADGRA2 | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1041754275, COSV55106110; called by muse, mutect2, varscan2
- ANO5 | c.2047G>T p.V683F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs770725167; called by muse, mutect2, varscan2
- ASIC3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.976); catalogued as rs762969627; called by muse, mutect2, varscan2
- BTBD7 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54140176; called by muse, mutect2, varscan2
- BX276092.9 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.06); catalogued as rs1216437398; called by muse, mutect2, varscan2
- CACNA1E | c.1859T>C p.L620P | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62409404; called by muse, mutect2, varscan2
- CCDC144A | c.3536T>C p.V1179A | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs1334294445, COSV60699329; called by muse, mutect2, varscan2
- CD28 | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.094); catalogued as COSV60730209, COSV60730252; called by muse, mutect2, varscan2
- CELSR2 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs780774580, COSV54772982; called by muse, mutect2, varscan2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2, varscan2
- COL23A1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953848452, COSV101178435, COSV66795751; called by muse, mutect2, varscan2
- GDF6 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.326); catalogued as rs561421783, COSV99747956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2D | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53517693; called by muse, mutect2, varscan2
- GSTM3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); catalogued as rs776366318; called by muse, mutect2, varscan2
- HAPLN1 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.174); catalogued as COSV57145547; called by muse, mutect2
- IGHA1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370788192; called by muse, varscan2
- KLC4 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769752349; called by muse, mutect2, varscan2
- MAPK3 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780719391, COSV53775801; called by muse, mutect2, varscan2
- NCAM2 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV53055705; called by muse, mutect2, varscan2
- PCDHA1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65372895; called by muse, mutect2, varscan2
- PLA2G2E | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774338921; called by muse, mutect2, varscan2
- RS1 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs760857618, COSV66106726; called by muse, mutect2, varscan2
- SALL1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs754846300, COSV51755108; called by muse, mutect2, varscan2
- SALL3 | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs749811334, COSV73306428; called by muse, mutect2, varscan2
- SAMD4A | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.298); catalogued as rs1157940887; called by muse, mutect2, varscan2
- SBSN | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs548106040, COSV71733101, COSV71733247; called by muse, mutect2, varscan2
- SERPINA4 | c.108C>A p.H36Q | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1241741364; called by muse, mutect2, varscan2
- SMC1B | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs772284288; called by muse, mutect2, varscan2
- UBR1 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as rs772603727, COSV99317786; called by muse, mutect2, varscan2
- UNC5A | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs371754063; called by muse, mutect2, varscan2
- ZNF214 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs911281102; called by muse, mutect2, varscan2
- ZZEF1 | c.4426C>T p.P1476S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV67555965; called by muse, mutect2, varscan2
- AC100868.1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ANXA3 | c.290del p.K97Sfs*3 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- ARHGAP24 | c.1754G>T p.G585V (on ENST00000395184 / NM_001025616.3; = p.G492V on NM_031305.3) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRWD3 | c.4966A>T p.K1656* | Nonsense Mutation (SNP) | VAF 56/172 reads (33%) | called by muse, mutect2, varscan2
- C6orf15 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- COG3 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- COL1A2 | c.3166G>T p.A1056S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL4A2 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CPSF2 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- CTNNB1 | c.1121G>C p.S374T | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CTSK | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DCHS1 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- EPHA10 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- FANCB | c.130_133del p.H44Sfs*23 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- FBN1 | c.8306C>T p.S2769F | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- FLG2 | c.3395G>A p.G1132E | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- INS | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- LYPD4 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC5B | c.16160G>A p.G5387E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NBEA | c.6862C>T p.R2288C | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR10AG1 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- RGS22 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNASE7 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ROBO2 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYT2 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SYT6 | c.882del p.F294Lfs*34 (on ENST00000610222 / NM_001366225.1; = p.F209Lfs*34 on NM_205848.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- ZNF680 | c.872A>T p.D291V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ADGRV1 | c.18879C>T p.I6293= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs372350188; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AK9 | c.2772G>A p.E924= | Silent (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.5172T>C p.N1724= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- DIP2B | c.189A>G p.V63= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- FAM181B | c.1074G>A p.A358= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs762284109; called by muse, mutect2
- FAT2 | c.2679G>A p.V893= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV99943355; called by muse, mutect2, varscan2
- FAT2 | c.1086C>T p.F362= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as rs200331562, COSV55815738; called by muse, mutect2, varscan2
- FTMT | c.186C>T p.A62= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs1367028314, COSV58420586; called by muse, mutect2, varscan2
- OR56B4 | c.447A>G p.K149= | Silent (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- PCLO | c.8637C>T p.V2879= | Silent (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- PTH1R | c.1005C>T p.F335= | Silent (SNP) | VAF 81/180 reads (45%) | called by muse, mutect2, varscan2
- RBSN | c.1956C>T p.D652= | Silent (SNP) | VAF 57/183 reads (31%) | catalogued as COSV99515248; called by muse, mutect2, varscan2
- SIGLEC6 | c.609C>A p.T203= | Silent (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- STARD9 | c.2283G>A p.R761= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as rs1173962744; called by muse, mutect2, varscan2
- TACC2 | c.6687C>T p.V2229= (on ENST00000334433; = p.V307= on NM_006997.4) | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as rs202168550, COSV53292126; called by muse, mutect2, varscan2
- TF | c.447C>T p.I149= | Silent (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2139T>G p.S713= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs756191679; called by muse, mutect2, varscan2
- TTLL5 | c.1635G>A p.K545= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- ZNF429 | c.1356C>T p.P452= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as COSV61914667; called by muse, mutect2, varscan2
- ZNF536 | c.2595C>G p.S865= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV62824468; called by muse, mutect2, varscan2
- AL158064.1 | chr13:80074540 A>G | 5'Flank (SNP) | VAF 48/137 reads (35%) | called by muse, mutect2, varscan2
- BRPF1 | c.3187+49G>A | Intron (SNP) | VAF 59/234 reads (25%) | called by muse, mutect2, varscan2
- CACNA1C | c.3946-18G>A | Intron (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- CFAP44 | chr3:113358745 C>T | 3'Flank (SNP) | VAF 32/111 reads (29%) | catalogued as rs1284829824, COSV55614867; called by muse, mutect2, varscan2
- DPP6 | c.243+7994C>T | Intron (SNP) | VAF 8/49 reads (16%) | called by mutect2, varscan2
- H2BP2 | n.238C>T | RNA (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- SORBS2 | c.-46+930G>A | Intron (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- UBE2E1 | c.484+99G>A | Intron (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
